Gene-level copy-number profile of tumor specimen HCM-CSHL-0060-C18-01B from HCMI case HCM-CSHL-0060-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 50.8 years (18,571 days).
Specimen HCM-CSHL-0060-C18-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 86c80c8b-deb2-496d-8620-585375aa42f5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0060-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/a40a7c22-c0d8-411f-bfc3-53455eae1e94

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 542; copy number 1: 10,548; copy number 2: 39,499; copy number 3: 4,887; copy number 4: 2,984; copy number 5: 319; copy number 6: 29; copy number 7: 1; copy number 9: 2; copy number 15: 45; copy number 22: 15; copy number 23: 31.

Homozygous deletions (total copy number 0; autosomes only): 30 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,502,145–49,589,529, 11 genes: ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr5:168,768,146–168,768,255, 1 gene (within-gene range 0–1): MIR218-2.
- chr7:76,474,587–76,478,856, 1 gene (within-gene range 0–2): AC005522.1.
- chr9:107,475,036–107,543,616, 4 genes: RNU6-492P, KLF4, AL389915.1, PPIAP88.
- chr9:132,375,548–132,573,319, 3 genes: TTF1, CFAP77, RNU5D-2P.
- chr15:99,970,215–99,974,010, 1 gene (within-gene range 0–1): AC084855.1.
- chr15:99,976,481–99,980,774, 1 gene (within-gene range 0–1): AC084855.2.
- chr16:16,094,192–16,095,209, 1 gene (within-gene range 0–2): RPL17P40.
- chr16:34,013,394–34,013,830, 1 gene: AC133561.2.
- chr17:2,748,078–2,748,182, 2 genes (within-gene range 0–2): MIR1253, hsa-mir-1253.
- chr21:43,053,191–43,076,943, 1 gene: CBS.
- chr22:18,101,612–18,103,649, 2 genes (within-gene range 0–1): AC016027.4, ARL2BPP10.
- chr22:45,435,864–45,448,743, 1 gene: AL021391.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 442 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,173,056–1,179,555, 1 gene, copy number 6 (within-gene range 3–6): TTLL10-AS1.
- chr7:57,014,285–57,061,301, 2 genes, copy number 6–7: SLC29A4P1, PHKG1P4.
- chr11:1,012,823–1,201,138, 4 genes, copy number 6: MUC6, LINC02688, MUC2, MUC5AC.
- chr13:20,138,255–22,276,526, 55 genes, copy number 15–23: GJA3, PPIAP28, LINC00556, GJB2, AL138688.1, GJB6, CRYL1, MIR4499, AL590096.1, IFT88, SLC35E1P1, RNU2-7P, AL161772.1, IL17D, AL512652.2, EEF1AKMT1, RANP8, AL512652.1, XPO4, CNOT4P1, HNRNPA1P30, PPIAP27, RPSAP54, LATS2, LATS2-AS1, RNU4-9P, RPS12P23, IPPKP1, AL161613.1, SNORD27, SAP18, SKA3, MRPL57, AL158032.1, LINC01046, ESRRAP2, AL158032.2, MIPEPP3, LINC00539, GRK6P1, GAPDHP52, RNA5SP25, ZDHHC20, ZDHHC20-IT1, H2BP6, MICU2, FNTAP2, RNU6-59P, RPS7P10, FGF9, RN7SL766P, LINC00424, LINC00540, NME1P1, MTND3P1.
- chr13:26,905,362–28,107,877, 36 genes, copy number 15–22: FGFR1OP2P1, AL160035.1, RPS21P8, RPS20P32, USP12, AL158062.1, USP12-AS1, USP12-AS2, LINC02340, LINC00412, RPL21, SNORD102, SNORA27, RASL11A, RNU6-70P, LINC01079, RNY1P1, GTF3A, MTIF3, RNU6-63P, LNX2, POLR1D, AL136439.1, NPM1P4, GSX1, PLUT, RNU6-73P, PDX1, ATP5F1EP2, LINC00543, CDX2, URAD, RN7SL272P, FLT3, KATNBL1P1, CHCHD2P8.
- chr13:31,739,526–45,536,701, 224 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr13:71,296,210–75,606,020, 48 genes, copy number 5–6 (within-gene range 4–6): RABEPKP1, DACH1, H3P36, RPL21P109, RPL35AP31, RPS10P21, AL139003.1, RPL18AP17, AL139003.2, AL356754.2, AL356754.1, RPL21P110, RNU6-80P, MZT1, BORA, DIS3, PIBF1, RNU6-79P, PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392, KLF12, AL138713.1, AL159972.1, LINC00402, AL353660.1, RNY1P5, RPL21P108, AL355390.1, LINC00381, AL355390.2, LINC00347, RIOK3P1, RNU6-38P, SSR1P2, CTAGE11P, LINC01078, TBC1D4, AL139230.1, COMMD6, UCHL3.
- chr16:525,155–1,276,522, 68 genes, copy number 5–9 (broad region; genes not listed).
- chr19:3,610,645–3,626,815, 1 gene, copy number 5 (within-gene range 2–5): CACTIN.
- chr20:3,471,018–3,651,118, 1 gene, copy number 5 (within-gene range 4–5): ATRN.
- chr20:45,252,239–45,254,564, 1 gene, copy number 5: SLPI.
- chr21:43,092,956–43,107,570, 1 gene, copy number 5: U2AF1.

Autosomal genes at a single copy (total copy number 1): 10,539. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
